Somatic mutation profile of tumor specimen TCGA-EE-A3JE-06A (aliquot TCGA-EE-A3JE-06A-11D-A20D-08) from TCGA case TCGA-EE-A3JE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.9 years (28,465 days).
Specimen TCGA-EE-A3JE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ee2cb32-c787-4d63-b329-5a8e5bf7c34c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JE-10A (Blood Derived Normal), aliquot TCGA-EE-A3JE-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba6347b8-9a7f-4fb0-a4a0-0215e0e4ade0

The open-access MAF lists 292 somatic variants for this specimen: 198 protein-altering or splice-affecting, 91 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 91, Nonsense Mutation 7, Splice Site 4, Intron 2, Frame Shift Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAD2 | c.1492G>A p.V498I (on ENST00000315906 / NM_001145400.2; = p.V580I on NM_139174.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV51895229; called by muse, mutect2
- ADAMTS16 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754871314, COSV56977587; called by muse, mutect2, varscan2
- ADGRV1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV67995151; called by muse, mutect2, varscan2
- ADGRV1 | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as COSV67995155; called by muse, mutect2
- AGR3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60037442; called by muse, mutect2, varscan2
- AHNAK | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57229892; called by muse, mutect2, varscan2
- ALAS2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV58193278; called by muse, mutect2, varscan2
- AMY2B | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63717044; called by muse, mutect2
- ANKRD12 | c.4760C>T p.S1587L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV50847852; called by muse, mutect2, varscan2
- ANO5 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.961); catalogued as rs746312346, COSV61090175; called by muse, mutect2, varscan2
- AP5Z1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV61068669; called by muse, mutect2, varscan2
- APBA1 | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55237370; called by muse, mutect2, varscan2
- APOB | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.306); catalogued as rs1319548654, COSV51951761; called by muse, mutect2
- ARHGEF12 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63107305; called by muse, mutect2, varscan2
- ARID2 | c.1120G>C p.G374R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57599553; called by muse, mutect2, varscan2
- ARID2 | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as COSV57607251; called by muse, mutect2
- AURKAIP1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV57940123; called by muse, mutect2, varscan2
- BIRC6 | c.11157G>T p.L3719F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770387826, COSV70205723; called by mutect2, varscan2
- BPIFB4 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs778887000, COSV100971549; called by mutect2, varscan2
- BTNL2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV66631878; called by muse, mutect2
- CACHD1 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51559879; called by muse, mutect2, varscan2
- CAND1 | c.1963C>T p.L655F | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101607328; called by muse, mutect2
- CCDC121 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1239080711, COSV53117528; called by muse, mutect2
- CCNB3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52079533, COSV99329954; called by muse, mutect2
- CD1E | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100936885, COSV63772865; called by muse, mutect2, varscan2
- CD33 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV51804747; called by muse, mutect2, varscan2
- CDC42BPA | c.4208C>T p.S1403L (on ENST00000334218 / NM_001366019.2; = p.S1390L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs770872855, COSV62001951, COSV62021475; called by muse, mutect2, varscan2
- CDH12 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV66425703, COSV66445567; called by muse, mutect2, varscan2
- CEP76 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs754183790, COSV50865624; called by muse, mutect2, varscan2
- CEP83 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV60411102; called by muse, mutect2, varscan2
- CETP | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52364331; called by muse, mutect2
- CIDEA | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV57600707; called by muse, mutect2, varscan2
- CLEC4G | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752077062, COSV61004151; called by muse, mutect2, varscan2
- CNTN3 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55183998, COSV99725022; called by muse, mutect2
- COG7 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56153139; called by muse, mutect2
- COL3A1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865823967, COSV58586183; called by mutect2, varscan2
- COL4A4 | c.2620C>T p.L874F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61636482; called by muse, mutect2, varscan2
- COL7A1 | c.8131T>C p.F2711L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56477255; called by muse, mutect2, varscan2
- CPN2 | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs749538876, COSV60471877; called by muse, mutect2, varscan2
- CRAMP1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1471862230, COSV51966029; called by muse, mutect2, varscan2
- CSMD2 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV53960999; called by muse, mutect2, varscan2
- CYP11B2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs143027239, COSV100010809; called by muse, mutect2, varscan2
- DCST1 | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764979994, COSV55054539; called by muse, mutect2, varscan2
- DDX11 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52500313, COSV52510645; called by muse, mutect2, varscan2
- DEFB125 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66703625; called by muse, mutect2, varscan2
- DENND4A | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764493217, COSV71267010; called by muse, mutect2, varscan2
- DHX16 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778054207, COSV51298690; called by muse, mutect2, varscan2
- DLC1 | c.4567A>G p.K1523E (on ENST00000276297 / NM_001348081.2; = p.K1086E on NM_006094.5) | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV52327316; called by muse, mutect2, varscan2
- DNAH10 | c.5761G>A p.E1921K (on ENST00000409039; = p.E1860K on NM_207437.3) | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753565239, COSV68992965; called by muse, mutect2, varscan2
- DNAH8 | c.12922C>T p.L4308F | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.515); catalogued as COSV59479611; called by muse, mutect2, varscan2
- DPP10 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV59726486; called by muse, mutect2
- DSCAML1 | c.1285G>A p.E429K (on ENST00000321322; = p.E369K on NM_020693.4) | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs777606240, COSV58399468; called by muse, mutect2, varscan2
- DSTYK | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV65688425; called by muse, mutect2, varscan2
- DUSP16 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV53809760; called by muse, mutect2, varscan2
- EDC3 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59341718; called by mutect2, varscan2
- EIF2AK3 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57552074; called by muse, mutect2
- EPS8L1 | c.58+1G>A p.X20_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as rs1260562572, COSV52386180; called by muse, mutect2, varscan2
- F13B | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747109019, COSV66372676, COSV66375650; called by muse, mutect2, varscan2
- FAM83H | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100567939; called by muse, mutect2, varscan2
- FASN | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs146356200; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FAT4 | c.9046G>A p.G3016R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377586866, COSV100628099; called by muse, mutect2
- FGFR2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV60641020; called by muse, mutect2, varscan2
- FLNB | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55894946; called by muse, mutect2, varscan2
- GAB4 | c.1476G>A p.P492= | Splice Region (SNP) | VAF 6/51 reads (12%) | catalogued as rs772156025, COSV68753699; called by mutect2, varscan2
- GALNT14 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100204911; called by muse, mutect2
- GALNTL6 | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101560527, COSV72493739; called by muse, mutect2, varscan2
- GAS2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764047229, COSV53404068; called by muse, mutect2, varscan2
- GFRA3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV99218423; called by muse, mutect2, varscan2
- GPR155 | c.286T>G p.S96A | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV55042149; called by muse, mutect2
- GRIA4 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56882122; called by muse, mutect2, varscan2
- HDAC2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV64038489; called by muse, mutect2
- HEATR5B | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV51858976; called by muse, mutect2
- HECTD3 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1366896631, COSV99870256; called by muse, mutect2, varscan2
- HMCN1 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1463611407, COSV54940403; called by muse, mutect2, varscan2
- HMGCS2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV65567069, COSV65569226; called by muse, mutect2, varscan2
- HS3ST1 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as COSV50026602; called by muse, mutect2
- HTR3B | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV52747619, COSV99491835; called by muse, mutect2, varscan2
- IFIT2 | c.483T>A p.F161L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51080673; called by muse, mutect2, varscan2
- IKBKB | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645590, COSV60599831; called by muse, mutect2
- ITGA5 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 24/208 reads (12%) | catalogued as rs1414929192, COSV53215620; called by muse, mutect2, varscan2
- JPH1 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs138696789; called by muse, mutect2
- KBTBD12 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59681939; called by muse, mutect2
- KHNYN | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52163426; called by muse, mutect2, varscan2
- KIF27 | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52831111; called by muse, mutect2, varscan2
- KRTAP10-12 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782603842, COSV100554099; called by muse, mutect2, varscan2
- LATS2 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359079402, COSV66880714; called by muse, mutect2, varscan2
- LENEP | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV52699948, COSV99422710; called by muse, mutect2, varscan2
- LEPR | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV60764356; called by muse, mutect2
- LIG1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV54395954; called by muse, mutect2
- LIPF | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs763307316, COSV53284027; called by muse, varscan2
- LRRC8A | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52189190; called by muse, mutect2, varscan2
- LRRN1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 5/89 reads (6%) | catalogued as COSV60016208; called by muse, mutect2
- MACF1 | c.8645C>T p.S2882F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV57143519, COSV99247390; called by muse, mutect2, varscan2
- MAGEA8 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV54065015; called by muse, mutect2, varscan2
- METTL2B | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV99299866; called by muse, mutect2, varscan2
- MFSD5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs563549259, COSV61565819; called by muse, mutect2, varscan2
- MTMR3 | c.938T>G p.L313W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV60308667; called by muse, mutect2
- MTUS2 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70917931, COSV70922434; called by muse, mutect2
- MUC16 | c.30821C>T p.S10274F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); catalogued as COSV67457826; called by muse, mutect2, varscan2
- MXRA5 | c.5230G>A p.G1744R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV54250028; called by muse, mutect2, varscan2
- MYB | c.53A>C p.D18A | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs980292268, COSV57201734; called by muse, mutect2
- MYH1 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV56851935; called by muse, mutect2
- MYH14 | c.4654C>G p.R1552G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51830903, COSV99222986; called by muse, mutect2, varscan2
- MYO3A | c.4579A>G p.K1527E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56348935; called by muse, mutect2
- MYT1L | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV67734413; called by muse, mutect2
- MYT1L | c.2005T>A p.S669T | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV101220949; called by muse, mutect2
- NFATC3 | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 18/257 reads (7%) | catalogued as COSV100285315; called by muse, mutect2
- NLRP11 | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64088777; called by muse, mutect2
- NOTCH4 | c.5270G>A p.G1757E | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66678505, COSV66683699; called by muse, mutect2, varscan2
- NRP1 | c.2572C>T p.L858F | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99588931; called by muse, mutect2, varscan2
- NTF3 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV58418386; called by muse, mutect2, varscan2
- OR10A3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs867656808, COSV62459900; called by muse, mutect2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, mutect2, varscan2
- OR4M1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60060003; called by muse, mutect2
- OR8D4 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs866009875, COSV58430971; called by muse, mutect2, varscan2
- OTC | c.948T>A p.F316L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV50004660; called by muse, mutect2, varscan2
- PAPPA2 | c.4274G>A p.R1425K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV62811222; called by muse, mutect2, varscan2
- PATJ | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57171981; called by muse, mutect2, varscan2
- PCDH15 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57270692, COSV57391701; called by muse, mutect2, varscan2
- PCDHB10 | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.261); catalogued as COSV53383663; called by muse, mutect2, varscan2
- PCDHB7 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.991); catalogued as COSV50769553; called by muse, mutect2
- PCNX1 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777713016, COSV53096036, COSV53098198; called by muse, mutect2, varscan2
- PHACTR3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63034093; called by muse, mutect2, varscan2
- PHF21B | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1296263301, COSV100503841; called by muse, mutect2
- PIEZO2 | c.6689C>T p.P2230L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53294042; called by muse, mutect2, varscan2
- PIK3CA | c.1135T>A p.S379T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV55993663; called by muse, mutect2, varscan2
- PKNOX2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV53554570; called by muse, mutect2
- PLXNA2 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV65444792; called by muse, mutect2, varscan2
- PNCK | c.773G>A p.R258K (on ENST00000340888 / NM_001366975.1; = p.R341K on NM_001039582.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1557039545, COSV61745440; called by muse, mutect2, varscan2
- PNMA8B | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100885448; called by muse, mutect2, varscan2
- POLN | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV67027619; called by muse, mutect2
- PPARGC1B | c.2911T>A p.S971T | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV58533005; called by muse, mutect2
- PPP2R5A | c.1329-1G>C p.X443_splice | Splice Site (SNP) | VAF 6/65 reads (9%) | catalogued as COSV54789620; called by muse, mutect2
- PRDM2 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769917250, COSV52455483; called by muse, mutect2, varscan2
- PRPF18 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as COSV60726183; called by muse, mutect2, varscan2
- PTPRC | c.1660-1G>A p.X554_splice | Splice Site (SNP) | VAF 16/185 reads (9%) | catalogued as COSV100722753; called by muse, mutect2
- PTPRC | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100722756; called by muse, mutect2
- PTPRF | c.3205C>G p.P1069A | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100740979; called by muse, mutect2, varscan2
- PTPRF | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740980; called by muse, mutect2, varscan2
- RBBP6 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1255790337, COSV60503618; called by muse, mutect2, varscan2
- RBM12 | c.1048T>G p.F350V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV58294986; called by muse, mutect2, varscan2
- RBMX | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57811468; called by muse, mutect2
- RELN | c.8503A>G p.R2835G | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV59033101; called by muse, mutect2, varscan2
- RHAG | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV57706001, COSV57706375; called by muse, mutect2, varscan2
- RHOC | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV53519278; called by muse, mutect2
- RP1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55110595, COSV55111673; called by muse, mutect2, varscan2
- RPS6KA6 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53118648; called by muse, mutect2
- RSBN1 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as COSV54735160; called by muse, mutect2, varscan2
- SCN11A | c.2775C>A p.D925E | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV56578257, COSV56579541; called by muse, mutect2, varscan2
- SDHAF2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57100200; called by muse, mutect2
- SEC24A | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as COSV59749802; called by muse, mutect2, varscan2
- SEMA3D | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52394807; called by muse, mutect2
- SERPINA3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs778637464, COSV101261730; called by muse, varscan2
- SFTA2 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV100764477; called by muse, mutect2, varscan2
- SFTA2 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100764479; called by muse, mutect2, varscan2
- SFXN4 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV57461014; called by muse, mutect2, varscan2
- SHC4 | c.1738-1G>A p.X580_splice | Splice Site (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100194704; called by muse, mutect2, varscan2
- SIK3 | c.3053G>A p.R1018Q (on ENST00000445177 / NM_001366686.2; = p.R976Q on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1385062419, COSV52619389; called by muse, mutect2
- SLC25A2 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53405018; called by muse, mutect2
- SLC25A33 | c.539C>G p.T180S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV100235768; called by muse, mutect2, varscan2
- SLC25A53 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100656021, COSV62460007; called by muse, mutect2, varscan2
- SLC34A1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV100183983; called by muse, mutect2, varscan2
- SLC46A1 | c.1279C>T p.L427F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV50229372; called by muse, mutect2, varscan2
- SLCO3A1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV59237194; called by muse, mutect2, varscan2
- SMC1B | c.815T>G p.M272R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV62533331; called by muse, mutect2
- SORCS3 | c.1073A>C p.E358A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63824252; called by muse, mutect2, varscan2
- SP100 | c.2289C>A p.F763L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.274); catalogued as COSV50980498, COSV50988876, COSV99893420; called by muse, mutect2, varscan2
- STPG2 | c.1091T>C p.M364T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1343856368, COSV54820560; called by muse, mutect2
- SULT1B1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as rs761640326, COSV60206584; called by muse, mutect2, varscan2
- TAS2R1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66778119; called by muse, mutect2, varscan2
- TBPL2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.411); catalogued as COSV55973771; called by muse, mutect2, varscan2
- TIGD3 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52891304; called by muse, mutect2, varscan2
- TLR1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58305604; called by muse, mutect2, varscan2
- TMC2 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV62658191; called by muse, mutect2, varscan2
- TMEM131L | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53650394; called by muse, mutect2, varscan2
- TMEM88 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV54686771; called by muse, mutect2, varscan2
- TRRAP | c.11177C>T p.P3726L (on ENST00000359863 / NM_001244580.1; = p.P3697L on NM_003496.3) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV104416812, COSV62815886, COSV62816799; called by muse, mutect2
- TSBP1 | c.1432G>A p.G478R (on ENST00000617061; = p.G483R on NM_006781.5) | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV66660848; called by muse, mutect2, varscan2
- TSBP1 | c.1162G>A p.G388R (on ENST00000617061; = p.G393R on NM_006781.5) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV66660842; called by muse, mutect2
- UBA3 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62741513; called by muse, mutect2, varscan2
- UBTF | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs532196673, COSV57186909; called by muse, mutect2, varscan2
- UGDH | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV57099867; called by muse, mutect2, varscan2
- USH2A | c.13346C>T p.S4449F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1378172593, COSV56434145; called by muse, mutect2, varscan2
- USP11 | c.1298G>A p.R433Q (on ENST00000218348; = p.R390Q on NM_001371072.1) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54475932; called by muse, mutect2
- USP20 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.433); catalogued as COSV100204401; called by muse, mutect2
- USP20 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.773); catalogued as COSV100204402; called by muse, mutect2
- VARS1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.69); catalogued as COSV65152331; called by muse, mutect2, varscan2
- VIRMA | c.4604C>T p.P1535L | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.998); catalogued as COSV52591190; called by muse, mutect2, varscan2
- VSIG2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV52518486; called by muse, mutect2, varscan2
- ZBED2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1472709399, COSV51922867; called by muse, mutect2, varscan2
- ZDHHC8 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100272680; called by muse, mutect2
- ZNF536 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.94); catalogued as rs201482419, COSV100834499; called by muse, mutect2
- ZNF836 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs781457359, COSV59086621; called by muse, mutect2, varscan2
- AP002748.5 | c.1798_1802del p.I600Qfs*36 | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel
- KDM4A | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ACE | c.762C>T p.L254= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs765396050, COSV52012788; called by muse, mutect2, varscan2
- ACSM1 | c.873C>T p.I291= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs867962448, COSV54633006; called by muse, mutect2, varscan2
- ADA2 | c.102G>A p.R34= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs113192455, COSV52833832; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS15 | c.2223C>T p.F741= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV54505781; called by muse, mutect2
- ADIPOQ | c.570G>A p.Q190= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV57860024; called by muse, mutect2, varscan2
- ANKRD29 | c.844C>T p.L282= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV52427791; called by muse, mutect2, varscan2
- BRD3 | c.633C>T p.V211= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV57706655; called by muse, mutect2
- C6orf118 | c.846G>A p.L282= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV57819058; called by muse, mutect2
- CAND1 | c.1962C>T p.I654= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV101607327; called by muse, mutect2
- CARNS1 | c.535C>T p.L179= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57132343; called by muse, mutect2
- CBFA2T2 | c.1611G>A p.E537= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs1018098501, COSV60802001; called by muse, mutect2, varscan2
- CCDC185 | c.1842C>T p.L614= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV64821846; called by muse, mutect2, varscan2
- CD300LD | c.156G>A p.R52= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV60084614; called by muse, mutect2, varscan2
- CDX1 | c.645G>A p.K215= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV51569328; called by muse, mutect2, varscan2
- CENPF | c.3690G>A p.E1230= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV65278972; called by muse, mutect2, varscan2
- CLPTM1 | c.1363C>T p.L455= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV61613063; called by muse, mutect2, varscan2
- CNDP2 | c.1332C>T p.A444= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV60841645; called by muse, mutect2, varscan2
- COMMD1 | c.402C>T p.H134= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV61280790; called by muse, mutect2, varscan2
- CRYBG2 | c.1011C>T p.S337= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV57490092; called by muse, mutect2
- CYP4F11 | c.879C>T p.S293= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV56129495; called by muse, mutect2, varscan2
- DCLRE1B | c.1470C>T p.T490= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs1485302423, COSV65813625; called by muse, mutect2
- DEF8 | c.414C>T p.F138= (on ENST00000268676 / NM_207514.3; = p.F77= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1323686814, COSV51921335; called by muse, mutect2
- DISP3 | c.1779C>T p.F593= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as COSV53837186; called by muse, mutect2, varscan2
- DLAT | c.348G>A p.G116= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV54773441; called by muse, mutect2
- DNAH5 | c.13275C>T p.S4425= | Silent (SNP) | VAF 27/273 reads (10%) | catalogued as rs370545463, COSV54230228, COSV54256966; called by muse, mutect2, varscan2
- ENC1 | c.78C>T p.S26= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100188033, COSV56631229; called by muse, mutect2, varscan2
- FAAH2 | c.1050G>A p.L350= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV66511495; called by muse, mutect2, varscan2
- FAM83H | c.3186C>T p.P1062= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1554621673, COSV100567938; called by muse, mutect2, varscan2
- FRYL | c.8562C>T p.N2854= | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as COSV99977152; called by muse, mutect2, varscan2
- GMEB1 | c.1506C>T p.S502= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs200465440; called by muse, mutect2
- GNAI3 | c.466C>T p.L156= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV63984512; called by muse, mutect2, varscan2
- GPI | c.376C>T p.L126= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV62894888; called by muse, mutect2
- GRID1 | c.1896C>T p.I632= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs773408585, COSV60052417; called by muse, mutect2, varscan2
- GRID1 | c.801C>T p.I267= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV60017428; called by muse, mutect2, varscan2
- GYPC | c.324C>T p.A108= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs764014645, COSV52148703; called by muse, mutect2
- HECTD3 | c.957C>T p.N319= | Silent (SNP) | VAF 39/335 reads (12%) | catalogued as COSV99870258; called by muse, mutect2, varscan2
- KCNH4 | c.768C>T p.T256= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV52920985; called by muse, mutect2, varscan2
- KDM4A | c.1248C>T p.P416= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV100969524; called by muse, mutect2
- KRTAP10-12 | c.117C>T p.P39= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs1486322274, COSV100554100; called by muse, mutect2, varscan2
- LATS1 | c.858C>T p.S286= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as COSV99486137; called by muse, mutect2
- LATS2 | c.1866C>T p.N622= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV101231588; called by muse, mutect2, varscan2
- MAD1L1 | c.366G>A p.E122= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV56247265; called by muse, mutect2, varscan2
- MARVELD3 | c.1179G>A p.E393= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99194835; called by muse, mutect2
- MCM2 | c.1002C>T p.F334= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as rs376347464, COSV54033010; called by muse, mutect2, varscan2
- MDM1 | c.639C>T p.F213= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV57448808; called by muse, mutect2
- MISP | c.1398C>T p.S466= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV53122279; called by muse, mutect2, varscan2
- MMP2 | c.1167C>T p.F389= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs766277938, COSV54605094; called by muse, mutect2, varscan2
- MYH1 | c.1767G>A p.V589= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1411727457, COSV99876165; called by muse, mutect2
- NAV2 | c.954C>T p.S318= (on ENST00000396087 / NM_001244963.2; = p.S295= on NM_145117.5) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV62332747; called by muse, mutect2, varscan2
- NEBL | c.2943C>T p.I981= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs201105598; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC3 | c.2946C>T p.G982= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV100285314; called by muse, mutect2
- NIPAL1 | c.510G>A p.G170= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV55006310; called by muse, mutect2, varscan2
- P4HA3 | c.951C>T p.I317= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV59043969; called by muse, mutect2, varscan2
- PCDHB3 | c.420G>A p.L140= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as COSV50564604; called by muse, mutect2, varscan2
- PHF21B | c.1584G>A p.Q528= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as rs767682321, COSV100503849; called by muse, mutect2
- PIGG | c.1827C>T p.L609= (on ENST00000453061 / NM_001127178.3; = p.L601= on NM_017733.4) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV56319871; called by muse, mutect2
- PLCG1 | c.840C>T p.F280= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs200581225, COSV54823920; called by muse, mutect2, varscan2
- PMFBP1 | c.276C>T p.V92= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV52831841; called by muse, mutect2
- PNMA8B | c.285C>T p.D95= | Silent (SNP) | VAF 25/243 reads (10%) | catalogued as COSV100885450; called by muse, mutect2, varscan2
- POU2F1 | c.462C>T p.S154= (on ENST00000541643 / NM_001365848.1; = p.S177= on NM_002697.4) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs766826910, COSV54824642; called by muse, mutect2, varscan2
- PRG4 | c.3144G>A p.T1048= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs769601354, COSV63355484; called by muse, mutect2, varscan2
- PROKR1 | c.774G>A p.E258= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV58139271; called by muse, mutect2
- PRR30 | c.600G>A p.K200= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV53208187; called by muse, mutect2
- PRUNE2 | c.210C>G p.T70= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV65026603, COSV65029562; called by muse, mutect2
- RXYLT1 | c.1161G>A p.K387= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV54167533, COSV54170074; called by muse, mutect2, varscan2
- SALL1 | c.3516G>A p.T1172= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs185193003, COSV51754516; called by muse, mutect2, varscan2
- SERPINA3 | c.960G>A p.R320= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV101261729; called by muse, varscan2
- SETDB2 | c.1074C>T p.N358= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV51643203; called by muse, mutect2
- SFI1 | c.2853G>A p.R951= (on ENST00000400288 / NM_001007467.3; = p.R920= on NM_014775.4) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56718833; called by muse, varscan2
- SIGLEC5 | c.354C>T p.F118= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV55781155; called by muse, mutect2
- SIK3 | c.3054G>A p.R1018= (on ENST00000445177 / NM_001366686.2; = p.R976= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99408179; called by muse, mutect2
- SKIV2L | c.2064C>T p.T688= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs764654308, COSV61715052; called by muse, mutect2, varscan2
- SLC25A33 | c.540C>T p.T180= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs767334485, COSV100235771, COSV100235921; called by muse, mutect2, varscan2
- SLC25A53 | c.384G>A p.E128= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100656022; called by muse, mutect2, varscan2
- SLC34A1 | c.1146C>T p.A382= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV100183986; called by muse, mutect2, varscan2
- SLC6A11 | c.1215C>T p.F405= | Silent (SNP) | VAF 21/229 reads (9%) | catalogued as rs1382260068, COSV54398943; called by muse, mutect2
- SRMS | c.555G>A p.R185= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV53922259; called by muse, mutect2, varscan2
- STOML2 | c.333C>T p.D111= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV59717551; called by muse, mutect2, varscan2
- STOX1 | c.1011C>T p.F337= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV53814392; called by muse, mutect2, varscan2
- TAS2R5 | c.858C>T p.I286= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV56095608; called by muse, mutect2, varscan2
- TENT5C | c.552C>T p.F184= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV65617122; called by muse, mutect2, varscan2
- THBS4 | c.384C>T p.L128= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as rs1173311310, COSV63470874; called by muse, mutect2, varscan2
- TRARG1 | c.165G>A p.Q55= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs767833099, COSV61563316; called by muse, mutect2
- TSHR | c.1788C>T p.I596= | Silent (SNP) | VAF 38/270 reads (14%) | catalogued as rs146917060; called by muse, mutect2, varscan2
- VPREB1 | c.147C>T p.I49= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs200837518, COSV56425512; called by muse, mutect2, varscan2
- VPS35 | c.1713G>A p.L571= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100140729, COSV54481187; called by muse, mutect2, varscan2
- WDR62 | c.3684C>T p.S1228= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- ZBTB2 | c.591C>T p.P197= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100287697; called by muse, mutect2
- ZDHHC8 | c.954C>T p.P318= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100272928; called by muse, mutect2
- ZFPM2 | c.900C>T p.F300= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV65875837; called by muse, mutect2
- ZNF658 | c.2136A>G p.K712= | Silent (SNP) | VAF 75/522 reads (14%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4569C>T | Intron (SNP) | VAF 40/202 reads (20%) | catalogued as COSV54858695, COSV99684773; called by muse, mutect2, varscan2
- DZANK1 | c.543+687C>T | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99362615; called by muse, mutect2, varscan2
- PRDM15 | c.-363C>T | 5'UTR (SNP) | VAF 9/109 reads (8%) | catalogued as COSV54157947; called by muse, mutect2
